Somatic mutation profile of tumor specimen ALCH-B4B1-TTP1-A (aliquot ALCH-B4B1-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4B1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.6 years (22,509 days).
Specimen ALCH-B4B1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17ea023c-ec33-445f-abb1-3576a0d13684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4B1-NB1-A (Blood Derived Normal), aliquot ALCH-B4B1-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b03462fb-5131-4699-bfe3-df3edf260acf

The open-access MAF lists 366 somatic variants for this specimen: 255 protein-altering or splice-affecting, 64 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 64, Nonsense Mutation 19, Intron 18, RNA 9, 3'UTR 7, Splice Site 6, 5'UTR 5, Frame Shift Del 4, 3'Flank 4, 5'Flank 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1906G>C p.G636R (on ENST00000288602 / NM_001374244.1; = p.G596R on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV55294071; called by muse, mutect2, varscan2
- A4GALT | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755424160; called by muse, mutect2, varscan2
- ABCC9 | c.4408C>T p.L1470F | Missense Mutation (SNP) | VAF 85/541 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.248); catalogued as COSV53963987; called by muse, mutect2, varscan2
- ACVR1C | c.1405G>C p.G469R | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54644304; called by muse, mutect2, varscan2
- AGRN | c.4805C>T p.P1602L | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as rs935763466, COSV65069363; called by muse, mutect2, varscan2
- ARHGEF10 | c.238G>T p.G80* (on ENST00000398564; = p.G56* on NM_014629.4) | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100034048; called by muse, mutect2
- AXDND1 | c.2916G>T p.K972N | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100858265; called by muse, varscan2
- BEST2 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs770731972, COSV104378090; called by muse, mutect2, varscan2
- BNC2 | c.2918G>T p.S973I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101035935; called by muse, mutect2
- BOD1L1 | c.8557G>T p.E2853* | Nonsense Mutation (SNP) | VAF 25/230 reads (11%) | catalogued as COSV50043969; called by muse, mutect2, varscan2
- BRINP3 | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 53/421 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as rs147308061; called by muse, mutect2, varscan2
- BTBD7 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 52/402 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs768644384; called by muse, mutect2, varscan2
- CAPN15 | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54835147; called by muse, mutect2, varscan2
- CBLN2 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.221); catalogued as COSV99504662; called by muse, mutect2, varscan2
- CBX4 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53964346, COSV99490630; called by muse, mutect2
- CECR2 | c.2494C>T p.R832* (on ENST00000342247 / NM_001290047.2; = p.R649* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 44/223 reads (20%) | catalogued as COSV52843326; called by muse, mutect2, varscan2
- CLCA4 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV55366940, COSV55369585; called by muse, mutect2
- COL11A2 | c.4099C>G p.L1367V (on ENST00000341947 / NM_080680.3; = p.L1260V on NM_080679.2) | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV59495810; called by muse, mutect2, varscan2
- COL4A1 | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 38/250 reads (15%) | catalogued as COSV65427963; called by muse, mutect2, varscan2
- CTC1 | c.1974G>T p.Q658H | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs779228652; called by muse, mutect2, varscan2
- CYP1B1 | c.1330C>G p.R444G | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM033367; called by mutect2, varscan2
- DHX57 | c.2311G>T p.E771* | Nonsense Mutation (SNP) | VAF 52/486 reads (11%) | catalogued as COSV54885872; called by muse, mutect2, varscan2
- DMWD | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52180830; called by muse, mutect2, varscan2
- DNAH10 | c.3451-3T>C | Splice Region (SNP) | VAF 34/206 reads (17%) | catalogued as rs752397692; called by muse, mutect2, varscan2
- EBLN1 | c.521G>C p.R174T | Missense Mutation (SNP) | VAF 70/449 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV69370178; called by muse, mutect2, varscan2
- FLNA | c.5124C>G p.F1708L (on ENST00000369850 / NM_001110556.2; = p.F1700L on NM_001456.3) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100775239; called by muse, mutect2
- FSCB | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1162808412, COSV61219458; called by muse, mutect2, varscan2
- FSD1 | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99696962; called by muse, mutect2, varscan2
- FSIP2 | c.4301A>G p.E1434G | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs919361839; called by muse, mutect2, varscan2
- H2AC8 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55126309; called by muse, mutect2
- HCN1 | c.1997C>G p.P666R | Missense Mutation (SNP) | VAF 75/540 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.806); catalogued as COSV100299771, COSV57492798, COSV57541621; called by muse, mutect2, varscan2
- HEPHL1 | c.3185C>A p.T1062N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59891866; called by muse, mutect2
- HSH2D | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV53740689; called by muse, mutect2, varscan2
- INO80 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV62736810; called by muse, mutect2
- IPO5 | c.787C>G p.L263V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs781237529; called by muse, mutect2, varscan2
- ITK | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 48/468 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as rs201892355; called by muse, mutect2
- KCNT2 | c.2611G>T p.G871C | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54071938, COSV54102577; called by muse, mutect2, varscan2
- KEAP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIF18B | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769124652; called by muse, mutect2, varscan2
- KLHL38 | c.1170del p.I391Lfs*38 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | catalogued as rs1351258817; called by pindel, varscan2
- KRT78 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs571219237; called by muse, mutect2, varscan2
- MED12 | c.4382C>T p.S1461L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1458136598; called by muse, mutect2, varscan2
- MUC16 | c.42033G>T p.Q14011H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66695444; called by muse, mutect2, varscan2
- MUC17 | c.7348C>A p.P2450T | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1446291796, COSV60284081; called by muse, mutect2, varscan2
- MYO1A | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 82/558 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs143549106, COSV55658136; called by muse, mutect2, varscan2
- NAV3 | c.4185G>T p.E1395D | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.914); catalogued as COSV57073782; called by muse, varscan2
- NPAP1 | c.3056G>T p.S1019I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV61513103; called by muse, mutect2, varscan2
- NUP188 | c.1874A>G p.N625S | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as rs769003262; called by muse, mutect2, varscan2
- OR10AG1 | c.381G>A p.M127I | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV56632693; called by muse, mutect2, varscan2
- OR13D1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV59515544; called by muse, mutect2, varscan2
- OR2T10 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV57898235; called by muse, mutect2, varscan2
- OR2W3 | c.841G>T p.V281F | Missense Mutation (SNP) | VAF 49/295 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1360686102; called by muse, mutect2, varscan2
- OR4M1 | c.70del p.Q24Nfs*2 | Frame Shift Del (DEL) | VAF 24/267 reads (9%) | catalogued as rs749159143, COSV60059477, COSV60062291; called by mutect2, pindel*
- OR6F1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100128947, COSV100129380; called by muse, mutect2
- OTOG | c.3966C>A p.H1322Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.968); catalogued as rs757220206; called by muse, mutect2, varscan2
- PARP12 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs149334393, COSV54932877; called by muse, mutect2
- POLM | c.1363T>C p.W455R | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.086); catalogued as rs746619462; called by muse, mutect2, varscan2
- POT1 | c.826A>T p.R276W | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV62927818; called by muse, mutect2, varscan2
- POTEC | c.859G>T p.V287L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV62803090; called by mutect2, varscan2
- PRDM15 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs772692177; called by muse, mutect2, varscan2
- PRDM5 | c.1188+1G>T p.X396_splice | Splice Site (SNP) | VAF 7/103 reads (7%) | catalogued as COSV53367819; called by muse, mutect2
- PRUNE2 | c.7268G>A p.G2423E | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs751180776; called by muse, mutect2
- RBL2 | c.1398G>A p.M466I | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.977); catalogued as COSV100043430; called by muse, mutect2, varscan2
- RBM10 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 35/103 reads (34%) | catalogued as COSV100237571; called by muse, mutect2, varscan2
- REG3A | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100532646, COSV59409762, COSV59410043; called by muse, mutect2, varscan2
- RYR1 | c.11947C>T p.R3983C | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM118233, COSV62101598; called by muse, mutect2, varscan2
- SI | c.4703C>A p.P1568H | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52279885, COSV52294175; called by muse, mutect2, varscan2
- SMOX | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1187896378; called by muse, mutect2, varscan2
- SPEG | c.2439C>T p.P813= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as rs372257767; called by mutect2, varscan2
- SPTA1 | c.6158C>T p.S2053L | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100934727; called by muse, mutect2, varscan2
- SYT4 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV99673344; called by muse, mutect2, varscan2
- TBL2 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs374301480; called by muse, mutect2, varscan2
- TMEM132D | c.3099G>T p.E1033D | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs762763245; called by muse, mutect2, varscan2
- TMOD1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs892684111, COSV52251421, COSV52251519; called by muse, mutect2
- TNXB | c.11179G>A p.V3727M (on ENST00000647633; = p.V3480M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs548190378; called by muse, mutect2
- TRIM51 | c.393G>T p.W131C | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV55269483; called by muse, mutect2, varscan2
- TRPV3 | c.2368G>T p.V790L | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV56790055; called by muse, mutect2, varscan2
- TTLL4 | c.2975A>G p.Q992R | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1393459130, COSV51437295; called by muse, mutect2
- USP7 | c.1510G>T p.D504Y | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61214399, COSV61214588; called by muse, mutect2
- ZEB2 | c.2492T>C p.I831T | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs746006843; called by muse, mutect2, varscan2
- ZIM2 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 35/218 reads (16%) | catalogued as rs1470532577; called by muse, mutect2, varscan2
- ZNF528 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs747080496; called by muse, mutect2, varscan2
- ZNF555 | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs770895322; called by muse, mutect2, varscan2
- ABCA1 | c.1756A>T p.M586L | Missense Mutation (SNP) | VAF 52/329 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC2 | c.1367G>T p.W456L | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCD2 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ABHD12 | c.240G>T p.L80F | Missense Mutation (SNP) | VAF 67/481 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- AC026316.4 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- ACVRL1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.052); called by muse, mutect2
- ADAMTS8 | c.877T>G p.F293V | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL2 | c.3732C>G p.S1244R (on ENST00000370717 / NM_001366005.1; = p.S1188R on NM_012302.4) | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AGAP1 | c.1865C>T p.S622F (on ENST00000304032 / NM_001037131.3; = p.S569F on NM_014914.5) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- AGPAT2 | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK2 | c.9641G>T p.G3214V | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- AKAP13 | c.5707A>G p.K1903E (on ENST00000394518 / NM_007200.5; = p.K1907E on NM_006738.6) | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANK2 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 81/622 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ANKS6 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ANP32E | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- APP | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 94/642 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, varscan2
- ATP11A | c.2839G>T p.D947Y | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1H | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- BSDC1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2
- C4orf54 | c.2987A>T p.Q996L | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CACNA1S | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 79/349 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC168 | c.13662G>C p.L4554F | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CCDC168 | c.4182G>T p.K1394N | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CELA3A | c.396C>A p.S132R | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- CENPP | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP126 | c.1355T>A p.I452N | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CFAP45 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COG1 | c.1019A>T p.H340L | Missense Mutation (SNP) | VAF 13/512 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- CREBL2 | c.311C>G p.S104* | Nonsense Mutation (SNP) | VAF 10/249 reads (4%) | called by muse, mutect2
- CSMD1 | c.8478C>A p.Y2826* (on ENST00000520002; = p.Y2825* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 17/202 reads (8%) | called by muse, mutect2
- CTBP1 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.007); called by mutect2, varscan2
- DNAH5 | c.4413G>T p.K1471N | Missense Mutation (SNP) | VAF 76/547 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- DNAH9 | c.4961T>C p.L1654P | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DPP10 | c.482A>T p.N161I | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DUSP16 | c.1668C>G p.S556R | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ELF3 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- ELMOD3 | c.606G>A p.Q202= | Splice Region (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- ELMOD3 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB6 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYA2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- EYA4 | c.1265T>C p.L422P (on ENST00000531901 / NM_001301013.1; = p.L416P on NM_004100.5) | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83B | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT2 | c.2908G>A p.G970R | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GJB4 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GLYATL3 | c.236A>G p.Y79C | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- GPA33 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR52 | c.17G>T p.W6L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRID1 | c.2406G>T p.Q802H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); called by muse, mutect2
- GRIN2B | c.1997T>A p.L666Q | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN3A | c.2056C>A p.H686N | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GRM3 | c.128del p.G43Afs*47 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- HECTD4 | c.3595G>T p.A1199S | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECW1 | c.1534G>T p.V512L | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- HOOK1 | c.788G>T p.R263M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXC6 | c.197G>C p.S66T | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2
- IGHM | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.25); called by muse, mutect2
- IGKV1-6 | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 101/778 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); called by mutect2, varscan2
- IL9 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 56/379 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- INF2 | c.1107G>T p.R369S | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INSRR | c.2941A>G p.I981V | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQCN | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2
- IRX3 | c.195_203del p.A68_A70del | In Frame Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, varscan2
- KCNU1 | c.1295+2T>A p.X432_splice | Splice Site (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- KIAA1210 | c.411-2A>T p.X137_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- KIF7 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- KIF7 | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2
- LAMC3 | c.324G>C p.M108I | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- LDHA | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 50/387 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- LILRB4 | c.1259C>A p.T420N (on ENST00000391733 / NM_001278428.3; = p.T419N on NM_001278426.3) | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- LIPJ | c.650T>A p.L217Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.03); called by muse, mutect2
- LRIG3 | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- MAP4K2 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MAP7D1 | c.1007G>T p.W336L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MARCHF11 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAST4 | c.6026G>T p.S2009I (on ENST00000403625 / NM_001164664.2; = p.S1820I on NM_015183.3) | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MCC | c.1691A>T p.E564V | Missense Mutation (SNP) | VAF 27/201 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCC | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MFGE8 | c.1052A>T p.H351L | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MMP27 | c.1097C>A p.T366K | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MROH2B | c.3639dup p.A1214Sfs*13 | Frame Shift Ins (INS) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- MT1A | c.94+1G>A p.X32_splice | Splice Site (SNP) | VAF 53/307 reads (17%) | called by muse, mutect2, varscan2
- MUC16 | c.27401G>A p.S9134N | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MYH7 | c.3397G>T p.E1133* | Nonsense Mutation (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2, varscan2
- MYO15A | c.6877C>A p.L2293I | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO18A | c.1312G>C p.A438P | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- NALCN | c.4186C>A p.H1396N | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- NAV3 | c.4214G>T p.S1405I | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NEBL | c.1677G>C p.K559N | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NEDD4L | c.1610G>T p.R537L (on ENST00000400345 / NM_001144967.3; = p.R517L on NM_015277.6) | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NFATC1 | c.2718G>T p.L906F (on ENST00000427363 / NM_001278669.2; = p.L893F on NM_172387.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NGDN | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIBAN1 | c.1607A>T p.H536L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.229); called by muse, mutect2
- NLRP2 | c.2845T>G p.L949V | Missense Mutation (SNP) | VAF 10/356 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2
- OBI1 | c.1454G>A p.G485E | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- OR1L3 | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- OR2T4 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 111/627 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR3A3 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR51T1 | c.579A>T p.K193N | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52R1 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR5AU1 | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- OR5F1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR5J2 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOG | c.308G>T p.R103L | Missense Mutation (SNP) | VAF 24/189 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- P3H3 | c.1613T>C p.V538A | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2
- PADI1 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PDGFRB | c.2857C>T p.Q953* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | called by muse, mutect2, varscan2
- PHF8 | c.3002A>T p.Q1001L (on ENST00000357988 / NM_001184896.1; = p.Q965L on NM_015107.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIEZO2 | c.4378G>T p.V1460L | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PITPNM1 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- PIWIL1 | c.2020G>T p.G674W | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLA2G4C | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PLA2G6 | c.2311G>T p.D771Y | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLAC8L1 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- POMT2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- POTEF | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PPA1 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPEF1 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PRAME | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- PRKAR1B | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- PRKG2 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRND | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PTPN13 | c.4868G>T p.C1623F (on ENST00000411767 / NM_080683.3; = p.C1604F on NM_006264.3) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.06); called by muse, mutect2
- PTPRQ | c.1832C>A p.P611Q (on ENST00000616559; = p.P569Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRZ1 | c.5143A>G p.S1715G | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RBM17 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2
- RDH10 | c.771-1G>T p.X257_splice | Splice Site (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2
- REC8 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- REELD1 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- RP1L1 | c.3065C>A p.P1022Q | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RSPO4 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RUNDC3A | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SCN8A | c.876T>A p.Y292* | Nonsense Mutation (SNP) | VAF 37/272 reads (14%) | called by muse, mutect2, varscan2
- SGCZ | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHKBP1 | c.1126G>C p.G376R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- SI | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SIGLEC9 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLAMF7 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- SLC38A6 | c.116G>T p.R39I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC6A3 | c.1327A>T p.R443* | Nonsense Mutation (SNP) | VAF 41/267 reads (15%) | called by muse, mutect2, varscan2
- SLC8A1 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SMARCAD1 | c.1058G>T p.R353I | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA31D1 | c.2261G>T p.R754I | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SPN | c.831G>T p.W277C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, varscan2
- STAB1 | c.3917del p.G1306Afs*31 | Frame Shift Del (DEL) | VAF 29/232 reads (13%) | called by mutect2, pindel, varscan2
- TENM4 | c.4055G>T p.G1352V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- TMEM108 | c.784A>G p.T262A | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, varscan2
- TMEM165 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.695); called by muse, mutect2
- TNFAIP2 | c.1155G>C p.Q385H | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TNFSF11 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2
- TNRC6B | c.5317G>T p.G1773W (on ENST00000454349 / NM_001162501.2; = p.G1663W on NM_015088.3) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBV20-1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRDN | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- TRRAP | c.3806A>T p.Q1269L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TTC8 | c.1353C>G p.N451K (on ENST00000338104 / NM_001288781.1; = p.N435K on NM_144596.4) | Missense Mutation (SNP) | VAF 110/771 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBAP2 | c.2653C>G p.Q885E | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- UNC79 | c.2905C>A p.P969T (on ENST00000393151 / NM_001346218.2; = p.P792T on NM_020818.5) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.822); called by muse, mutect2
- UQCRC2 | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 75/637 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- UQCRC2 | c.1069C>A p.Q357K | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- USP24 | c.7315-1G>T p.X2439_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- VWA5B1 | c.2146A>T p.S716C | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- WDFY4 | c.6692G>T p.R2231I | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- XKR3 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 13/241 reads (5%) | called by muse, mutect2
- ZIC3 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF135 | c.1820A>T p.E607V (on ENST00000313434 / NM_001289401.2; = p.E619V on NM_003436.4) | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZNF274 | c.387G>T p.Q129H (on ENST00000610905; = p.Q24H on NM_016324.3) | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZNF536 | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF567 | c.893A>T p.D298V (on ENST00000536254 / NM_001322913.1; = p.D267V on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZNF583 | c.858T>A p.H286Q | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF641 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 28/548 reads (5%) | called by muse, mutect2
- ZP4 | c.1385T>A p.L462H | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ZZZ3 | c.1792G>C p.V598L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ABCA9 | c.3504C>A p.T1168= | Silent (SNP) | VAF 14/175 reads (8%) | catalogued as rs1172185436; called by muse, mutect2
- ACTN2 | c.2475C>G p.T825= | Silent (SNP) | VAF 90/587 reads (15%) | catalogued as rs758805815, COSV63978535; called by muse, mutect2, varscan2
- ADHFE1 | c.705G>T p.V235= | Silent (SNP) | VAF 38/335 reads (11%) | called by muse, mutect2, varscan2
- ASPM | c.702A>C p.A234= | Silent (SNP) | VAF 100/364 reads (27%) | catalogued as rs752306785; called by muse, mutect2, varscan2
- ATXN2L | c.1341G>T p.P447= | Silent (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- BCAS3 | c.1875C>T p.H625= (on ENST00000390652 / NM_001353144.2; = p.H610= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/411 reads (12%) | called by muse, mutect2, varscan2
- BSX | c.525A>G p.E175= | Silent (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- CASS4 | c.1341G>T p.L447= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as rs758762274; called by muse, mutect2, varscan2
- CCDC168 | c.8520G>T p.L2840= | Silent (SNP) | VAF 27/225 reads (12%) | called by muse, mutect2, varscan2
- CCR9 | c.768C>A p.T256= (on ENST00000357632 / NM_031200.3; = p.T244= on NM_006641.4) | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100591621; called by muse, mutect2
- CD163L1 | c.921C>G p.T307= | Silent (SNP) | VAF 52/354 reads (15%) | called by muse, mutect2, varscan2
- CDH22 | c.2376G>T p.S792= | Silent (SNP) | VAF 13/256 reads (5%) | catalogued as rs940635947; called by muse, mutect2
- CEACAM18 | c.426C>T p.S142= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs976702180, COSV67282830; called by muse, mutect2, varscan2
- CEP162 | c.1452A>G p.K484= | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2
- COQ5 | c.723G>T p.R241= | Silent (SNP) | VAF 20/410 reads (5%) | called by muse, mutect2
- CPT1B | c.1503C>A p.T501= | Silent (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- CUX2 | c.2856C>T p.F952= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- DSC3 | c.1248T>A p.V416= | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- F13A1 | c.112C>A p.R38= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2
- FAM193B | c.516G>C p.S172= | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- FGF10 | c.291G>A p.K97= | Silent (SNP) | VAF 67/451 reads (15%) | catalogued as COSV52932852; called by muse, mutect2, varscan2
- HECTD1 | c.237A>G p.T79= | Silent (SNP) | VAF 49/392 reads (13%) | catalogued as rs985767271; called by muse, mutect2, varscan2
- IL1RL1 | c.1566C>G p.S522= | Silent (SNP) | VAF 30/273 reads (11%) | catalogued as COSV52117880; called by muse, mutect2
- KANK4 | c.504G>T p.T168= | Silent (SNP) | VAF 36/188 reads (19%) | catalogued as COSV100587191, COSV62987701; called by muse, mutect2, varscan2
- KCNC4 | c.483C>T p.F161= | Silent (SNP) | VAF 25/136 reads (18%) | catalogued as rs1354378932; called by muse, mutect2, varscan2
- KLF11 | c.741C>T p.G247= | Silent (SNP) | VAF 40/254 reads (16%) | catalogued as rs765025458; called by muse, mutect2, varscan2
- KLHL38 | c.1164C>T p.I388= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs373917760; called by muse, varscan2
- LHX5 | c.669C>A p.V223= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, varscan2
- MAST3 | c.534G>A p.E178= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- NGEF | c.2061C>A p.V687= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- NPC1 | c.1485G>T p.L495= | Silent (SNP) | VAF 67/410 reads (16%) | called by muse, mutect2, varscan2
- NWD2 | c.4434G>T p.G1478= | Silent (SNP) | VAF 48/347 reads (14%) | catalogued as rs1445588940; called by muse, mutect2, varscan2
- OR14C36 | c.109C>T p.L37= | Silent (SNP) | VAF 25/200 reads (13%) | catalogued as COSV58601206, COSV58602950; called by muse, mutect2, varscan2
- OR2L2 | c.858C>G p.P286= | Silent (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- OR4F15 | c.54C>A p.T18= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as rs963633583; called by muse, mutect2
- OR4N2 | c.345T>G p.L115= | Silent (SNP) | VAF 40/712 reads (6%) | called by muse, mutect2
- OR52A1 | c.477C>A p.A159= | Silent (SNP) | VAF 35/336 reads (10%) | catalogued as rs747453667; called by muse, mutect2, varscan2
- OR6C2 | c.471A>T p.P157= | Silent (SNP) | VAF 41/295 reads (14%) | called by muse, mutect2, varscan2
- OTOGL | c.3858C>A p.V1286= (on ENST00000547103; = p.V1277= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/251 reads (10%) | called by muse, mutect2, varscan2
- PDE1C | c.1738C>A p.R580= | Silent (SNP) | VAF 54/504 reads (11%) | called by muse, mutect2, varscan2
- PHF3 | c.1215G>A p.A405= | Silent (SNP) | VAF 30/290 reads (10%) | catalogued as rs764463727; called by muse, mutect2, varscan2
- PI4KB | c.1842C>A p.V614= (on ENST00000368873 / NM_001369623.1; = p.V626= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 58/343 reads (17%) | called by muse, mutect2, varscan2
- PKM | c.318G>T p.R106= | Silent (SNP) | VAF 31/301 reads (10%) | called by muse, mutect2, varscan2
- RIPOR3 | c.2358G>A p.K786= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV50387965; called by muse, mutect2
- RYR1 | c.5275C>A p.R1759= | Silent (SNP) | VAF 33/226 reads (15%) | catalogued as COSV100615910, COSV62098979; called by muse, mutect2, varscan2
- RYR2 | c.7020G>T p.G2340= | Silent (SNP) | VAF 43/338 reads (13%) | catalogued as rs767884614, COSV63687686; called by muse, mutect2, varscan2
- SCN4A | c.696C>G p.V232= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- SDK2 | c.5208C>A p.T1736= | Silent (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.1281G>A p.E427= (on ENST00000308713 / NM_001114099.3; = p.E357= on NM_012410.4) | Silent (SNP) | VAF 27/144 reads (19%) | called by muse, mutect2, varscan2
- SH3TC2 | c.1023C>T p.L341= | Silent (SNP) | VAF 18/665 reads (3%) | called by muse, mutect2
- SLC1A7 | c.558G>T p.G186= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs533479598; called by muse, mutect2, varscan2
- SLC39A5 | c.1344G>A p.L448= | Silent (SNP) | VAF 14/231 reads (6%) | catalogued as rs1222742320; called by muse, mutect2
- SLX4 | c.3879G>A p.R1293= | Silent (SNP) | VAF 29/185 reads (16%) | called by muse, mutect2, varscan2
- SMTNL1 | c.48C>G p.S16= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1210641952; called by muse, mutect2, varscan2
- SUCLG1 | c.444C>T p.P148= | Silent (SNP) | VAF 97/689 reads (14%) | catalogued as rs373153604; called by muse, mutect2, varscan2
- TMEM132E | c.1083C>T p.I361= (on ENST00000321639; = p.I451= on NM_001304438.2) | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- TMEM229A | c.498G>T p.A166= | Silent (SNP) | VAF 22/199 reads (11%) | called by muse, varscan2
- TRAV8-7 | c.261C>T p.S87= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs776876958; called by muse, mutect2, varscan2
- TRPM6 | c.2322C>T p.S774= | Silent (SNP) | VAF 49/381 reads (13%) | called by muse, mutect2, varscan2
- ULBP2 | c.114C>T p.T38= | Silent (SNP) | VAF 23/309 reads (7%) | catalogued as rs768784947; called by muse, mutect2, varscan2
- UMAD1 | c.258G>A p.L86= | Silent (SNP) | VAF 16/548 reads (3%) | catalogued as rs1330600258; called by muse, mutect2
- ZFP92 | c.1146G>T p.R382= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ZNF280B | c.831G>A p.K277= | Silent (SNP) | VAF 49/360 reads (14%) | catalogued as COSV100840260; called by muse, mutect2, varscan2
- ZNF395 | c.1536G>C p.L512= | Silent (SNP) | VAF 45/410 reads (11%) | called by muse, mutect2
- AC099552.1 | n.268G>T | RNA (SNP) | VAF 32/290 reads (11%) | called by muse, mutect2, varscan2
- ANKRD44 | c.1184-11G>T | Intron (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- AP000851.2 | n.249T>C | RNA (SNP) | VAF 63/401 reads (16%) | catalogued as rs1024107903; called by muse, mutect2, varscan2
- APTX | c.-111+147C>T | Intron (SNP) | VAF 36/347 reads (10%) | catalogued as COSV58927557; called by muse, mutect2, varscan2
- ARHGEF4 | c.39+649G>T | Intron (SNP) | VAF 8/65 reads (12%) | catalogued as rs1351902878; called by muse, mutect2, varscan2
- BBS2 | c.-8C>A | 5'UTR (SNP) | VAF 34/281 reads (12%) | called by muse, mutect2, varscan2
- C12orf43 | c.188+37A>T | Intron (SNP) | VAF 37/277 reads (13%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65213898 T>G | 3'Flank (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- CCDC74A | c.251-147A>G | Intron (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2
- CCN2 | c.67-42C>A | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs985683514; called by muse, mutect2, varscan2
- CD8A | c.*388C>G | 3'UTR (SNP) | VAF 14/122 reads (11%) | catalogued as rs1368149844; called by muse, mutect2, varscan2
- COL28A1 | c.1998+962G>T | Intron (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- COPA | c.1529-21C>A | Intron (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- COPS2 | c.-8C>T | 5'UTR (SNP) | VAF 32/235 reads (14%) | catalogued as rs371972527; called by muse, mutect2, varscan2
- CPN1 | c.*33C>G | 3'UTR (SNP) | VAF 35/301 reads (12%) | catalogued as COSV100962549; called by muse, mutect2, varscan2
- CTNNBL1 | c.-55G>T | 5'UTR (SNP) | VAF 10/207 reads (5%) | catalogued as COSV63743533; called by muse, mutect2
- CXorf65 | c.-25T>A | 5'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- DAAM2 | c.*2265G>A | 3'UTR (SNP) | VAF 32/160 reads (20%) | called by muse, mutect2, varscan2
- DAO | chr12:108879813 C>A | 5'Flank (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- EIF3L | c.1576-9C>T | Intron (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- FHL1 | c.*572T>A | 3'UTR (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- GTF2F1 | chr19:6396404 G>T | 5'Flank (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- GTF2F1 | chr19:6396405 G>T | 5'Flank (SNP) | VAF 26/91 reads (29%) | called by muse, mutect2, varscan2
- GVINP1 | n.4859C>A | RNA (SNP) | VAF 36/250 reads (14%) | called by muse, mutect2, varscan2
- HK1 | c.28-3325A>T | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- KREMEN2 | c.1099+33G>A | Intron (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- MAP4 | c.1999+4076C>T | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- MIR519B | n.67G>A | RNA (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- NBPF22P | n.939C>A | RNA (SNP) | VAF 34/290 reads (12%) | called by muse, mutect2, varscan2
- NLGN4Y | c.*1869A>G | 3'UTR (SNP) | VAF 61/201 reads (30%) | called by muse, mutect2, varscan2
- OR3A4P | n.847C>A | RNA (SNP) | VAF 42/383 reads (11%) | called by muse, mutect2
- POLN | c.2309-69G>T | Intron (SNP) | VAF 19/145 reads (13%) | catalogued as rs201334698; called by muse, mutect2, varscan2
- PRR14L | chr22:31676917 G>A | 3'Flank (SNP) | VAF 28/229 reads (12%) | called by muse, mutect2, varscan2
- RASA4CP | n.648G>T | RNA (SNP) | VAF 18/140 reads (13%) | called by muse, varscan2
- RBM22 | c.54+39G>A | Intron (SNP) | VAF 7/188 reads (4%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159250 G>T | 5'Flank (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928477 C>T | 3'Flank (SNP) | VAF 13/114 reads (11%) | called by muse, mutect2, varscan2
- SNORD116-25 | n.73A>T | RNA (SNP) | VAF 12/322 reads (4%) | called by muse, mutect2
- SPEN | c.404+1043A>T | Intron (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- SPHK2 | chr19:48630602 C>A | 3'Flank (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- SPI1 | c.493+88C>A | Intron (SNP) | VAF 14/113 reads (12%) | called by muse, varscan2
- SPI1 | c.493+87C>A | Intron (SNP) | VAF 14/112 reads (13%) | called by muse, varscan2
- STMN4 | c.-5G>A | 5'UTR (SNP) | VAF 26/316 reads (8%) | called by muse, mutect2
- TBC1D32 | c.*497C>T | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- TMCO1 | c.*903A>G | 3'UTR (SNP) | VAF 54/315 reads (17%) | catalogued as rs986557609; called by muse, mutect2, varscan2
- TTYH3 | c.124-1049G>T | Intron (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- UBTFL2 | n.541G>T | RNA (SNP) | VAF 33/329 reads (10%) | called by muse, mutect2, varscan2
